Gene-level copy-number profile of tumor specimen TCGA-XX-A89A-01A from TCGA case TCGA-XX-A89A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (25,000 days).
Specimen TCGA-XX-A89A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e6031cb7-3b18-4a8e-a40a-c1c86066b9a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XX-A89A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e9d56ac-80cc-457b-88a5-fe121f067599

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 12,589; copy number 4: 10,961; copy number 5: 17; copy number 6: 35,362; copy number 7: 1; copy number 9: 368; copy number 14: 23; copy number 16: 40; copy number 17: 94; copy number 19: 3; copy number 20: 37; copy number 21: 1; copy number 23: 60; copy number 26: 57; copy number 28: 84; copy number 32: 11; copy number 34: 40; copy number 39: 1; copy number 40: 26; copy number 58: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XX-A89A-01A-11D-A36I-01): tumor purity 0.34, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 520 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,881,566–44,651,724, 162 genes, copy number 17–32 (within-gene range 4–32) (broad region; genes not listed).
- chr1:111,200,771–115,102,658, 103 genes, copy number 20–28 (within-gene range 4–28) (broad region; genes not listed).
- chr11:66,257,294–67,050,863, 55 genes, copy number 23: KLC2, AP001107.8, AP001107.7, RAB1B, AP001107.1, AP001107.2, CNIH2, YIF1A, TMEM151A, AP001107.3, CD248, RIN1, AP001107.6, BRMS1, B4GAT1, AP001107.9, SLC29A2, Metazoa_SRP, BRD9P1, RNU1-84P, AP001107.5, NPAS4, AP002748.1, MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860.
- chr11:68,754,620–71,670,297, 82 genes, copy number 20–40 (broad region; genes not listed).
- chr11:71,690,453–71,705,404, 2 genes, copy number 40: SNRPCP14, AP003498.1.
- chr11:77,659,996–80,528,066, 45 genes, copy number 20–58: RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P.
- chr11:80,957,317–81,556,425, 5 genes, copy number 23: AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr19:13,862,063–13,880,757, 3 genes, copy number 19: NANOS3, MIR181C, MIR181D.
- chr19:13,906,201–14,293,205, 23 genes, copy number 14 (within-gene range 3–14): CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.3, AC011509.2, AC011509.1.
- chr19:14,789,260–14,835,376, 1 gene, copy number 16 (within-gene range 3–16): OR7C1.
- chr19:14,826,241–15,584,709, 39 genes, copy number 16: OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
